Somatic mutation profile of cancer-model specimen HCM-BROD-0577-C15-85M (3D Organoid, passage 7; aliquot HCM-BROD-0577-C15-85M-01D-A83U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0577-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Age at diagnosis: 63.0 years (23,026 days).
Specimen HCM-BROD-0577-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22da5d3b-e780-4e3f-a175-5b1a593f7720.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0577-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0577-C15-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1df93875-a1df-413a-bc5a-b4b45b9650a0

The open-access MAF lists 224 somatic variants for this specimen: 153 protein-altering or splice-affecting, 62 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 136, Silent 62, Nonsense Mutation 9, Intron 6, Frame Shift Del 3, Frame Shift Ins 2, 5'Flank 1, In Frame Del 1, Splice Site 1, 3'UTR 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 70/306 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS17 | c.1482G>A p.M494I | Missense Mutation (SNP) | VAF 91/388 reads (23%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.535); catalogued as rs1426558794; called by muse, mutect2, varscan2
- ADGRL3 | c.874C>T p.R292C (on ENST00000506720 / NM_001322402.2; = p.R224C on NM_015236.6) | Missense Mutation (SNP) | VAF 362/362 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746274680, COSV72268662; called by muse, mutect2, varscan2
- APC | c.4037C>A p.S1346* | Nonsense Mutation (SNP) | VAF 413/413 reads (100%) | catalogued as COSV57325995, COSV57328373, COSV57364395; called by muse, mutect2, varscan2
- ARNT | c.2099G>A p.R700H | Missense Mutation (SNP) | VAF 283/443 reads (64%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as rs192996355; called by muse, mutect2, varscan2
- BCL11A | c.1612C>T p.R538C (on ENST00000335712 / NM_001365609.1; = p.R572C on NM_018014.4) | Missense Mutation (SNP) | VAF 314/966 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs768167495; called by muse, mutect2, varscan2
- C8orf34 | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 162/772 reads (21%) | SIFT deleterious, low confidence (0); catalogued as rs970911902; called by muse, mutect2, varscan2
- CCDC106 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 137/743 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs199745701; called by muse, mutect2, varscan2
- CEACAM5 | c.2081G>A p.G694E | Missense Mutation (SNP) | VAF 172/737 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV55751514; called by muse, mutect2, varscan2
- CNTNAP1 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 443/975 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99226467; called by muse, mutect2, varscan2
- COL7A1 | c.6647G>A p.G2216E | Missense Mutation (SNP) | VAF 34/371 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as rs781720055; called by muse, mutect2
- DNAH6 | c.9350G>A p.R3117Q | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs992951674, COSV52883193; called by muse, mutect2, varscan2
- DSEL | c.2877A>C p.Q959H | Missense Mutation (SNP) | VAF 372/372 reads (100%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.698); catalogued as rs182255712, COSV100025798; called by muse, mutect2, varscan2
- EMILIN2 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 304/768 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs778731918, COSV99598495; called by muse, mutect2, varscan2
- EVC2 | c.3002C>A p.A1001E | Missense Mutation (SNP) | VAF 346/346 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60388197; called by muse, mutect2, varscan2
- FAM222A | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 510/787 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143726568; called by muse, mutect2, varscan2
- FAM83D | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 343/1432 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs924398974; called by muse, varscan2
- FBXO10 | c.781C>T p.H261Y | Missense Mutation (SNP) | VAF 32/684 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs775296496; called by muse, mutect2
- FREM2 | c.3418G>T p.D1140Y | Missense Mutation (SNP) | VAF 34/843 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV104382624; called by muse, mutect2
- FREM3 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 266/565 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV61679162; called by muse, mutect2, varscan2
- GAGE13 | c.87C>T p.P29= | Splice Region (SNP) | VAF 56/160 reads (35%) | catalogued as rs1275635006; called by mutect2, varscan2
- GYG1 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 110/393 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1046264003; called by muse, varscan2
- HAS2 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 89/281 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1294249506; called by muse, mutect2, varscan2
- HELZ | c.4696G>A p.E1566K | Missense Mutation (SNP) | VAF 216/494 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as rs747434999, COSV62376151; called by muse, mutect2
- HSP90B1 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1381329965; called by muse, mutect2, varscan2
- IER3 | c.416C>G p.S139W | Missense Mutation (SNP) | VAF 322/1125 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs762827505; called by muse, mutect2, varscan2
- IGFALS | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 722/723 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as rs145465654, COSV51904855; called by muse, mutect2, varscan2
- IKZF2 | c.564G>T p.R188S | Missense Mutation (SNP) | VAF 94/351 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59578633; called by muse, mutect2, varscan2
- KCNN4 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 115/554 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs778075609; called by muse, mutect2, varscan2
- KRT38 | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 70/317 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs768404914, COSV99878221, COSV99878323; called by muse, mutect2, varscan2
- LAMA1 | c.7639G>A p.V2547I | Missense Mutation (SNP) | VAF 278/472 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs367598361; called by muse, mutect2, varscan2
- MAP3K5 | c.3082C>T p.H1028Y | Missense Mutation (SNP) | VAF 100/350 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.433); catalogued as COSV62890282; called by muse, mutect2, varscan2
- MTNR1B | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 251/508 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.849); catalogued as rs764536870, COSV57068453; called by muse, mutect2, varscan2
- NCK2 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 214/648 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV51888998; called by muse, varscan2
- NFKB2 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 478/1032 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs774941850; called by muse, mutect2, varscan2
- NRK | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 261/261 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV54606532; called by mutect2, varscan2
- NTRK1 | c.2297G>A p.R766Q | Missense Mutation (SNP) | VAF 834/1301 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs764581997, COSV104423323, COSV62323137; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR56A4 | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 194/610 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as rs889408530; called by muse, mutect2, varscan2
- PKLR | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 305/970 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs1336522710, COSV61360721; called by muse, mutect2, varscan2
- PLSCR4 | c.749G>A p.C250Y | Missense Mutation (SNP) | VAF 300/479 reads (63%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV100724292; called by muse, mutect2, varscan2
- POLR3E | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 161/954 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as rs752474199; called by muse, mutect2, varscan2
- PRKAA1 | c.1589C>T p.S530F | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.736); catalogued as rs1394656931, COSV62628988; called by muse, mutect2, varscan2
- PSD2 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 304/672 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs201057651; called by muse, mutect2, varscan2
- ROBO2 | c.2390G>T p.R797L | Missense Mutation (SNP) | VAF 111/307 reads (36%) | SIFT tolerated (0.9); PolyPhen benign (0.067); catalogued as rs201678507, CM084999, COSV59905570; called by muse, mutect2, varscan2
- RPL27A | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 326/535 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs777153516; called by muse, varscan2
- SLC6A15 | c.511C>G p.Q171E | Missense Mutation (SNP) | VAF 93/314 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as rs1454815811, COSV57029168; called by muse, mutect2, varscan2
- SMARCA2 | c.2815C>A p.H939N | Missense Mutation (SNP) | VAF 75/255 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM122557; called by muse, mutect2, varscan2
- TATDN2 | c.625C>G p.R209G | Missense Mutation (SNP) | VAF 242/524 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV55050469; called by muse, mutect2, varscan2
- TJP2 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 317/1237 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs754080705, COSV55267291; called by muse, mutect2, varscan2
- TMEM47 | c.401C>A p.P134Q | Missense Mutation (SNP) | VAF 303/303 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750916621, COSV52067262; called by muse, mutect2, varscan2
- TRPV6 | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 144/350 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs748307676; called by muse, mutect2, varscan2
- ZBTB45 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 289/1191 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.108); catalogued as rs1184262730; called by muse, mutect2, varscan2
- ZFP69B | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 103/387 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.051); catalogued as rs576740711, COSV64316161; called by muse, mutect2, varscan2
- ZNF208 | c.1715A>C p.K572T | Missense Mutation (SNP) | VAF 172/403 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV68107459; called by muse, mutect2, varscan2
- ZNF211 | c.1117G>A p.E373K (on ENST00000347302 / NM_198855.4; = p.E386K on NM_006385.5) | Missense Mutation (SNP) | VAF 225/980 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs781751403, COSV53743999, COSV99560352; called by muse, mutect2, varscan2
- ZNF750 | c.2162G>A p.R721Q | Missense Mutation (SNP) | VAF 129/576 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs531996649; called by muse, mutect2, varscan2
- ADAM17 | c.2063G>C p.S688T | Missense Mutation (SNP) | VAF 104/347 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- AK8 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 108/616 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- ANAPC2 | c.2104C>T p.Q702* | Nonsense Mutation (SNP) | VAF 502/1064 reads (47%) | called by muse, varscan2
- ANKRD9 | c.326G>A p.C109Y | Missense Mutation (SNP) | VAF 26/940 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); called by muse, mutect2
- ARHGAP11B | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 70/241 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ARID1A | c.6436A>T p.K2146* | Nonsense Mutation (SNP) | VAF 580/926 reads (63%) | called by muse, mutect2, varscan2
- ASPM | c.4159G>T p.V1387F | Missense Mutation (SNP) | VAF 130/235 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- CABP1 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 387/1204 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CCDC168 | c.18383A>T p.K6128M | Missense Mutation (SNP) | VAF 272/648 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCNF | c.1697C>A p.S566* | Nonsense Mutation (SNP) | VAF 115/414 reads (28%) | called by muse, mutect2, varscan2
- CFAP91 | c.420G>C p.K140N | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- CHIT1 | c.566C>A p.T189N | Missense Mutation (SNP) | VAF 323/499 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CILK1 | c.1450G>C p.D484H (on ENST00000350082 / NM_001375397.1; = p.D477H on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 193/614 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CLDN5 | c.206C>T p.S69L (on ENST00000618236 / NM_001363066.2; = p.S154L on NM_003277.4) | Missense Mutation (SNP) | VAF 288/860 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CNST | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 380/604 reads (63%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CTNNA3 | c.2616A>T p.R872S | Missense Mutation (SNP) | VAF 179/720 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DHRS12 | c.806C>G p.S269C (on ENST00000444610 / NM_001377930.1; = p.S220C on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 272/1495 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- DMRTA2 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 259/572 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DPYD | c.2345C>G p.A782G | Missense Mutation (SNP) | VAF 151/318 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- FAAP24 | c.577G>C p.G193R | Missense Mutation (SNP) | VAF 170/793 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM117B | c.1657G>C p.A553P | Missense Mutation (SNP) | VAF 380/580 reads (66%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- FBXO30 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 25/632 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- FBXO8 | c.944G>A p.G315D | Missense Mutation (SNP) | VAF 98/235 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLG2 | c.5768del p.H1923Lfs*479 | Frame Shift Del (DEL) | VAF 150/637 reads (24%) | called by mutect2, pindel, varscan2
- GLG1 | c.1361G>A p.G454E | Missense Mutation (SNP) | VAF 24/615 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2
- GPR156 | c.2195C>T p.S732L | Missense Mutation (SNP) | VAF 259/780 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GRHL3 | c.1763C>G p.P588R | Missense Mutation (SNP) | VAF 193/619 reads (31%) | SIFT tolerated, low confidence (0.5); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- H4C2 | c.194_220del p.N65_Y73del | In Frame Del (DEL) | VAF 225/426 reads (53%) | called by mutect2, pindel, varscan2
- HDLBP | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 32/692 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.056); called by muse, mutect2
- HSD3B7 | c.320A>G p.Q107R | Missense Mutation (SNP) | VAF 33/563 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.216); called by muse, mutect2
- IL11RA | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 336/532 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- INSL6 | c.19T>G p.L7V | Missense Mutation (SNP) | VAF 137/468 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IRX4 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 345/642 reads (54%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPRIPL2 | c.430C>G p.P144A | Missense Mutation (SNP) | VAF 277/821 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- KIFC1 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 351/1150 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- KL | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 311/1538 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KRT25 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); called by muse, mutect2
- KRT6A | c.1468C>T p.Q490* | Nonsense Mutation (SNP) | VAF 172/560 reads (31%) | called by muse, varscan2
- KRTAP4-11 | c.255C>G p.C85W | Missense Mutation (SNP) | VAF 261/1595 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LAMA1 | c.3239G>T p.G1080V | Missense Mutation (SNP) | VAF 604/989 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LILRB4 | c.1307C>G p.S436C (on ENST00000391733 / NM_001278428.3; = p.S435C on NM_001278426.3) | Missense Mutation (SNP) | VAF 161/776 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- MAGEL2 | c.3720C>G p.H1240Q | Missense Mutation (SNP) | VAF 264/453 reads (58%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MDN1 | c.9871C>T p.P3291S | Missense Mutation (SNP) | VAF 24/556 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MEPE | c.129C>A p.D43E | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MGAM2 | c.1-1G>C p.X1_splice | Splice Site (SNP) | VAF 102/263 reads (39%) | called by muse, mutect2, varscan2
- MLNR | c.791G>C p.S264T | Missense Mutation (SNP) | VAF 624/1509 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MPDZ | c.5582G>A p.R1861K (on ENST00000319217 / NM_001330637.2; = p.R1832K on NM_003829.5) | Missense Mutation (SNP) | VAF 61/240 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- MPHOSPH8 | c.1213G>T p.E405* | Nonsense Mutation (SNP) | VAF 127/596 reads (21%) | called by muse, mutect2, varscan2
- MUC16 | c.18406G>A p.E6136K | Missense Mutation (SNP) | VAF 170/614 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- MUC16 | c.3854C>A p.S1285* | Nonsense Mutation (SNP) | VAF 190/570 reads (33%) | called by muse, mutect2, varscan2
- MYH7B | c.5714A>G p.D1905G | Missense Mutation (SNP) | VAF 310/652 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- NDUFB7 | c.138G>A p.M46I | Missense Mutation (SNP) | VAF 52/798 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); called by muse, mutect2
- NID1 | c.755G>A p.S252N | Missense Mutation (SNP) | VAF 109/342 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NLGN4X | c.1217T>G p.L406R | Missense Mutation (SNP) | VAF 97/339 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- OR4C3 | c.386A>T p.H129L | Missense Mutation (SNP) | VAF 421/684 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- PDCD7 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 133/1425 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- PDZD8 | c.2135dup p.N712Kfs*22 | Frame Shift Ins (INS) | VAF 326/913 reads (36%) | called by mutect2, pindel, varscan2
- PIEZO2 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 90/521 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PPP1R10 | c.1612_1628del p.E538Wfs*4 | Frame Shift Del (DEL) | VAF 118/854 reads (14%) | called by mutect2, pindel, varscan2
- PPP1R3F | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 440/442 reads (100%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM9 | c.1220T>A p.V407E | Missense Mutation (SNP) | VAF 173/342 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- PREX1 | c.2015A>G p.N672S | Missense Mutation (SNP) | VAF 357/760 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- PTPRO | c.728A>G p.Q243R | Missense Mutation (SNP) | VAF 127/457 reads (28%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RBAK | c.1370A>T p.Y457F | Missense Mutation (SNP) | VAF 18/580 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); called by muse, mutect2
- RIOK1 | c.302G>C p.S101T | Missense Mutation (SNP) | VAF 64/383 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RNF213 | c.5089G>A p.E1697K | Missense Mutation (SNP) | VAF 201/871 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- RPTN | c.1845A>T p.R615S | Missense Mutation (SNP) | VAF 170/589 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SDR16C5 | c.726G>C p.L242F | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- SH3KBP1 | c.1151G>C p.R384T | Missense Mutation (SNP) | VAF 11/368 reads (3%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); called by muse, mutect2
- SLC16A14 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 167/578 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- SLC6A4 | c.686A>T p.E229V | Missense Mutation (SNP) | VAF 225/473 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SLCO1B3 | c.1808C>T p.S603F | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); called by muse, varscan2
- SLIT1 | c.3994A>G p.K1332E | Missense Mutation (SNP) | VAF 467/1066 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SOX3 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 70/478 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- SOX30 | c.1671dup p.A558Cfs*9 | Frame Shift Ins (INS) | VAF 527/738 reads (71%) | called by mutect2, pindel, varscan2
- SP9 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SPATA46 | c.285G>T p.W95C | Missense Mutation (SNP) | VAF 181/537 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA5 | c.2581C>T p.H861Y | Missense Mutation (SNP) | VAF 273/273 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- SPECC1L | c.2896C>G p.L966V | Missense Mutation (SNP) | VAF 141/470 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STXBP5L | c.1566G>A p.W522* | Nonsense Mutation (SNP) | VAF 168/329 reads (51%) | called by muse, mutect2, varscan2
- TCF7 | c.658_662del p.L220Ffs*73 | Frame Shift Del (DEL) | VAF 315/321 reads (98%) | called by mutect2, pindel, varscan2
- TEX15 | c.6243G>C p.K2081N (on ENST00000256246; = p.K2464N on NM_001350162.2) | Missense Mutation (SNP) | VAF 118/291 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TEX15 | c.6079G>C p.D2027H (on ENST00000256246; = p.D2410H on NM_001350162.2) | Missense Mutation (SNP) | VAF 94/227 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- THAP1 | c.14G>A p.C5Y | Missense Mutation (SNP) | VAF 194/550 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAF7 | c.1147C>G p.Q383E | Missense Mutation (SNP) | VAF 130/462 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TRIM62 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 242/762 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- TRIM64B | c.979T>C p.F327L | Missense Mutation (SNP) | VAF 345/678 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- TRPM6 | c.4860G>T p.E1620D | Missense Mutation (SNP) | VAF 191/484 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPS1 | c.3281T>C p.L1094P (on ENST00000220888 / NM_001330599.2; = p.L1107P on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/453 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- TTC22 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 81/970 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by muse, mutect2
- TTC27 | c.2276A>C p.E759A | Missense Mutation (SNP) | VAF 86/316 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- VCAN | c.4897A>C p.S1633R | Missense Mutation (SNP) | VAF 315/315 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- VWDE | c.3863A>G p.K1288R | Missense Mutation (SNP) | VAF 38/406 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2
- ZNF112 | c.2526C>G p.F842L (on ENST00000337401 / NM_001083335.2; = p.F836L on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 208/832 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- ZNF141 | c.1161A>T p.K387N | Missense Mutation (SNP) | VAF 196/395 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ZNF723 | c.1523C>A p.S508* | Nonsense Mutation (SNP) | VAF 51/294 reads (17%) | called by muse, mutect2, varscan2
- ZNF829 | c.428T>G p.L143R | Missense Mutation (SNP) | VAF 205/394 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- AADACL3 | c.663C>A p.I221= | Silent (SNP) | VAF 171/570 reads (30%) | catalogued as rs747575830; called by muse, mutect2, varscan2
- ABCC8 | c.969C>T p.I323= | Silent (SNP) | VAF 180/630 reads (29%) | catalogued as rs748659098, COSV56850831; called by muse, mutect2, varscan2
- CCDC63 | c.1431G>A p.P477= | Silent (SNP) | VAF 187/597 reads (31%) | catalogued as rs201517807, COSV57527110; called by muse, mutect2, varscan2
- CDHR5 | c.2013G>A p.A671= (on ENST00000358353 / NM_001171968.2; = p.A677= on NM_021924.5) | Silent (SNP) | VAF 440/1412 reads (31%) | catalogued as rs758394688; called by muse, mutect2, varscan2
- CDHR5 | c.807G>T p.L269= | Silent (SNP) | VAF 237/766 reads (31%) | called by muse, mutect2, varscan2
- CECR2 | c.3627G>A p.P1209= (on ENST00000342247 / NM_001290047.2; = p.P1025= on NM_001290046.1) | Silent (SNP) | VAF 184/621 reads (30%) | catalogued as rs367605937; called by muse, mutect2, varscan2
- CELA3B | c.597G>A p.K199= | Silent (SNP) | VAF 89/421 reads (21%) | catalogued as rs1173262954; called by muse, mutect2, varscan2
- CEMIP | c.780C>T p.F260= | Silent (SNP) | VAF 161/481 reads (33%) | called by muse, mutect2, varscan2
- CSDE1 | c.153C>T p.F51= | Silent (SNP) | VAF 89/236 reads (38%) | called by muse, mutect2, varscan2
- CYP2D7 | c.1437G>A p.L479= | Silent (SNP) | VAF 264/1416 reads (19%) | catalogued as rs1387908141; called by muse, mutect2, varscan2
- DAB1 | c.942G>A p.A314= (on ENST00000371231; = p.A281= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 112/320 reads (35%) | catalogued as rs749228212, COSV64695803; called by muse, mutect2, varscan2
- DCAF8L1 | c.1263C>T p.L421= | Silent (SNP) | VAF 33/360 reads (9%) | called by muse, mutect2
- DENND6A | c.1774T>C p.L592= | Silent (SNP) | VAF 127/302 reads (42%) | catalogued as rs779758729; called by muse, mutect2, varscan2
- GFM2 | c.1953T>G p.T651= | Silent (SNP) | VAF 274/274 reads (100%) | called by muse, mutect2, varscan2
- GNAS | c.378C>T p.F126= | Silent (SNP) | VAF 36/1028 reads (4%) | called by muse, mutect2
- GTF2H4 | c.711C>T p.L237= | Silent (SNP) | VAF 28/665 reads (4%) | catalogued as rs752680523; called by muse, mutect2
- HDAC5 | c.3069C>A p.L1023= | Silent (SNP) | VAF 173/694 reads (25%) | catalogued as COSV99291183; called by muse, mutect2, varscan2
- HRNR | c.1239C>T p.R413= | Silent (SNP) | VAF 438/667 reads (66%) | catalogued as rs752238836, COSV64261879; called by muse, mutect2, varscan2
- IPCEF1 | c.1077C>T p.I359= | Silent (SNP) | VAF 189/303 reads (62%) | catalogued as COSV54540511, COSV54548437; called by muse, mutect2, varscan2
- IPO5 | c.75C>A p.V25= | Silent (SNP) | VAF 38/1133 reads (3%) | called by muse, mutect2
- ITPA | c.360C>T p.L120= | Silent (SNP) | VAF 52/814 reads (6%) | catalogued as rs1043378050; called by muse, mutect2
- KIF26A | c.1746G>A p.A582= | Silent (SNP) | VAF 352/698 reads (50%) | catalogued as rs915648835; called by muse, mutect2, varscan2
- KLHDC9 | c.126C>T p.L42= | Silent (SNP) | VAF 52/1022 reads (5%) | catalogued as rs1175784767, COSV63509399; called by muse, mutect2
- LGALS9 | c.303C>G p.L101= | Silent (SNP) | VAF 59/395 reads (15%) | called by muse, mutect2, varscan2
- LRRC20 | c.162C>A p.L54= | Silent (SNP) | VAF 196/763 reads (26%) | called by muse, mutect2, varscan2
- LRRC41 | c.162G>A p.V54= | Silent (SNP) | VAF 230/789 reads (29%) | called by muse, mutect2, varscan2
- MAGI1 | c.324G>A p.L108= | Silent (SNP) | VAF 24/302 reads (8%) | called by muse, mutect2
- MDM1 | c.1512T>C p.S504= | Silent (SNP) | VAF 75/279 reads (27%) | catalogued as rs1246854427; called by muse, mutect2, varscan2
- MED15 | c.396G>T p.G132= | Silent (SNP) | VAF 41/693 reads (6%) | called by muse, mutect2
- MTUS1 | c.3147G>A p.L1049= (on ENST00000262102 / NM_001363061.1; = p.L215= on NM_020749.4) | Silent (SNP) | VAF 268/309 reads (87%) | called by muse, mutect2, varscan2
- MXRA5 | c.7935C>T p.N2645= | Silent (SNP) | VAF 322/702 reads (46%) | catalogued as COSV54243771; called by muse, mutect2, varscan2
- MYF6 | c.531G>A p.A177= | Silent (SNP) | VAF 147/437 reads (34%) | catalogued as COSV57353464; called by muse, mutect2, varscan2
- NLRC5 | c.3924G>A p.L1308= | Silent (SNP) | VAF 494/495 reads (100%) | called by muse, mutect2, varscan2
- NPAT | c.1587G>A p.K529= | Silent (SNP) | VAF 20/166 reads (12%) | catalogued as COSV53715981; called by muse, mutect2, varscan2
- OR11G2 | c.339C>A p.T113= | Silent (SNP) | VAF 205/386 reads (53%) | called by muse, mutect2, varscan2
- OR8H3 | c.13A>C p.R5= | Silent (SNP) | VAF 108/108 reads (100%) | called by muse, mutect2, varscan2
- PLCD3 | c.399C>T p.F133= | Silent (SNP) | VAF 343/1450 reads (24%) | catalogued as rs962539626, COSV59560962; called by muse, mutect2, varscan2
- PRODH2 | c.1518G>A p.R506= (on ENST00000301175; = p.R430= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 402/847 reads (47%) | catalogued as rs776588763, COSV56560307; called by muse, mutect2, varscan2
- QPRT | c.201C>A p.L67= | Silent (SNP) | VAF 249/884 reads (28%) | catalogued as COSV54879788; called by muse, mutect2, varscan2
- RAD21 | c.204C>T p.H68= | Silent (SNP) | VAF 57/351 reads (16%) | catalogued as rs918914974; called by muse, mutect2, varscan2
- RBM28 | c.2073C>T p.P691= | Silent (SNP) | VAF 180/365 reads (49%) | catalogued as rs770210501, COSV56165037; called by muse, mutect2, varscan2
- RPL4 | c.126C>T p.T42= | Silent (SNP) | VAF 227/646 reads (35%) | called by muse, mutect2, varscan2
- RPRD1A | c.822G>C p.L274= | Silent (SNP) | VAF 139/343 reads (41%) | called by muse, mutect2, varscan2
- RREB1 | c.3246G>A p.L1082= | Silent (SNP) | VAF 82/897 reads (9%) | catalogued as rs541215584; called by muse, mutect2
- RTEL1 | c.1044C>T p.I348= | Silent (SNP) | VAF 268/651 reads (41%) | catalogued as rs762614267; called by muse, mutect2, varscan2
- SEMA5B | c.534T>A p.T178= | Silent (SNP) | VAF 391/615 reads (64%) | called by muse, mutect2, varscan2
- SLC12A1 | c.1869C>T p.I623= | Silent (SNP) | VAF 34/842 reads (4%) | called by muse, mutect2
- SLC52A2 | c.237C>T p.V79= | Silent (SNP) | VAF 244/656 reads (37%) | catalogued as rs1554853879; called by muse, mutect2, varscan2
- SPHKAP | c.1011A>C p.A337= | Silent (SNP) | VAF 157/537 reads (29%) | called by muse, mutect2, varscan2
- TAF4 | c.2277G>A p.T759= | Silent (SNP) | VAF 301/1260 reads (24%) | catalogued as rs1359261096; called by muse, mutect2, varscan2
- TKFC | c.720C>T p.L240= | Silent (SNP) | VAF 178/388 reads (46%) | called by muse, mutect2, varscan2
- TLN2 | c.1878G>A p.L626= | Silent (SNP) | VAF 160/529 reads (30%) | called by muse, mutect2, varscan2
- TMEM39B | c.504C>T p.L168= | Silent (SNP) | VAF 69/816 reads (8%) | catalogued as COSV100298011; called by muse, mutect2
- TONSL | c.1506G>A p.P502= | Silent (SNP) | VAF 436/593 reads (74%) | catalogued as rs779139647; called by muse, mutect2, varscan2
- TRIM39-RPP21 | c.1185G>A p.A395= | Silent (SNP) | VAF 222/940 reads (24%) | called by muse, mutect2, varscan2
- TTN | c.17148T>C p.A5716= (on ENST00000591111; = p.A4789= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 168/504 reads (33%) | called by muse, mutect2, varscan2
- UBR2 | c.4176T>C p.L1392= | Silent (SNP) | VAF 141/402 reads (35%) | called by muse, mutect2, varscan2
- ZC3H11B | c.2271A>T p.R757= | Silent (SNP) | VAF 256/763 reads (34%) | called by muse, mutect2, varscan2
- ZNF219 | c.1620G>A p.S540= | Silent (SNP) | VAF 209/499 reads (42%) | catalogued as rs763617351; called by muse, mutect2, varscan2
- ZNF263 | c.1191G>A p.Q397= | Silent (SNP) | VAF 173/493 reads (35%) | called by muse, mutect2, varscan2
- ZNF277 | c.1212C>T p.D404= | Silent (SNP) | VAF 89/181 reads (49%) | called by muse, mutect2, varscan2
- ZNF71 | c.1050C>T p.G350= | Silent (SNP) | VAF 548/1133 reads (48%) | catalogued as rs758955497; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81156890 G>A | 3'Flank (SNP) | VAF 390/390 reads (100%) | catalogued as rs767856105; called by muse, mutect2, varscan2
- IL36B | c.261+918C>G | Intron (SNP) | VAF 177/636 reads (28%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1393+27119G>A | Intron (SNP) | VAF 34/434 reads (8%) | called by muse, mutect2
- LINC02615 | chr4:128466647 G>C | 5'Flank (SNP) | VAF 172/328 reads (52%) | called by muse, mutect2, varscan2
- NCALD | c.*213G>A | 3'UTR (SNP) | VAF 50/452 reads (11%) | called by muse, mutect2, varscan2
- NSUN4 | c.94-1236G>A | Intron (SNP) | VAF 123/341 reads (36%) | catalogued as rs962752887; called by muse, mutect2, varscan2
- SEC16A | c.6313-98C>T | Intron (SNP) | VAF 107/551 reads (19%) | called by muse, mutect2, varscan2
- ST3GAL3 | c.254+9898G>C | Intron (SNP) | VAF 25/630 reads (4%) | called by muse, mutect2
- TTN | c.10303+1197A>T | Intron (SNP) | VAF 31/759 reads (4%) | called by muse, mutect2
